CCDI case PBCHRS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/217f727c-f4f2-4fd6-aeaf-965645b956cf

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 14.7 years (5,385 days).

Biospecimens (3 samples)
- Sample 0DS536: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS543: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSCOD: Tissue type: Tumor; Specimen type: Solid Tissue.
